Somatic mutation profile of tumor specimen 0DK84F from CCDI case PBBXMW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 2.5 years (927 days).
Specimen 0DK84F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bfc3d917-af1e-40dd-bfbb-836d8b6ddda4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK83T (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd90b9ae-c234-4ca7-8f69-fa613f45ce9d

The open-access MAF lists 44 somatic variants for this specimen: 31 protein-altering or splice-affecting, 7 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 7, Intron 4, Splice Site 4, Nonsense Mutation 1, 5'UTR 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMDHD1 | c.367G>T p.V123L | Missense Mutation (SNP) | VAF 83/458 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV57139331, COSV99900284; called by muse, mutect2, varscan2
- ARHGEF6 | c.1085C>T p.S362L | Missense Mutation (SNP) | VAF 43/423 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.314); catalogued as rs369636192; called by muse, mutect2, varscan2
- C1orf158 | c.419A>G p.Y140C | Missense Mutation (SNP) | VAF 50/472 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751235420; called by muse, mutect2, varscan2
- DNAH11 | c.9424G>T p.G3142C | Missense Mutation (SNP) | VAF 60/535 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60947428; called by mutect2, varscan2
- KCNJ18 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 26/750 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1484861594; called by muse, mutect2
- LNPK | c.455C>A p.P152Q | Missense Mutation (SNP) | VAF 103/504 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1047317430; called by muse, mutect2, varscan2
- MYL2 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 90/550 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.241); catalogued as rs370075755; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYRF | c.1469G>A p.R490H (on ENST00000278836 / NM_001127392.3; = p.R481H on NM_013279.4) | Missense Mutation (SNP) | VAF 44/769 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99607782; called by muse, mutect2
- OR4A15 | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 38/368 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.179); catalogued as rs143514871; called by muse, mutect2, varscan2
- TOM1L2 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 29/493 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV58884881; called by muse, mutect2
- ARHGEF17 | c.3664-1G>A p.X1222_splice | Splice Site (SNP) | VAF 28/729 reads (4%) | called by muse, mutect2
- CACNA1D | c.4691-1G>A p.X1564_splice (on ENST00000350061 / NM_001128840.3; = p.X1584_splice on NM_000720.4) | Splice Site (SNP) | VAF 40/286 reads (14%) | called by muse, mutect2, varscan2
- CEP68 | c.404T>A p.L135Q | Missense Mutation (SNP) | VAF 171/856 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- ELFN1 | c.146C>A p.P49H | Missense Mutation (SNP) | VAF 60/395 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HERC6 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 42/356 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- LRRC7 | c.1517A>T p.E506V (on ENST00000651989 / NM_001370785.2; = p.E473V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/630 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MED17 | c.36A>C p.E12D | Missense Mutation (SNP) | VAF 131/617 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- MROH2A | c.3256C>T p.L1086F | Missense Mutation (SNP) | VAF 30/664 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); called by muse, mutect2
- NKRF | c.837A>T p.E279D | Missense Mutation (SNP) | VAF 92/551 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- PRAMEF17 | c.498C>G p.Y166* | Nonsense Mutation (SNP) | VAF 75/542 reads (14%) | called by muse, mutect2, varscan2
- SACS | c.9580T>A p.L3194M | Missense Mutation (SNP) | VAF 25/489 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.014); called by muse, mutect2
- SNTG1 | c.28-2A>G p.X10_splice | Splice Site (SNP) | VAF 12/386 reads (3%) | called by muse, mutect2
- SULF2 | c.416-1G>A p.X139_splice | Splice Site (SNP) | VAF 63/451 reads (14%) | called by muse, mutect2, varscan2
- SYCP2 | c.3081T>G p.D1027E | Missense Mutation (SNP) | VAF 75/823 reads (9%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); called by muse, mutect2
- TEC | c.1447A>T p.N483Y | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- TGFBR2 | c.1254G>A p.Q418= | Splice Region (SNP) | VAF 73/228 reads (32%) | called by muse, mutect2, varscan2
- TLR4 | c.2438A>T p.K813I (on ENST00000355622 / NM_138554.5; = p.K773I on NM_003266.4) | Missense Mutation (SNP) | VAF 133/301 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- TOP3B | c.1158C>A p.D386E | Missense Mutation (SNP) | VAF 100/1356 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- USP51 | c.2004C>A p.S668R | Missense Mutation (SNP) | VAF 70/518 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by mutect2, varscan2
- ZNF582 | c.770G>A p.C257Y | Missense Mutation (SNP) | VAF 130/1087 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ZNF726 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 31/320 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); called by muse, mutect2
- MAN2B1 | c.2229C>T p.F743= | Silent (SNP) | VAF 28/932 reads (3%) | catalogued as COSV55472098; called by muse, mutect2
- NUP62CL | c.336T>C p.N112= | Silent (SNP) | VAF 52/447 reads (12%) | catalogued as COSV65235559; called by muse, mutect2, varscan2
- PCDH11X | c.2370T>A p.T790= | Silent (SNP) | VAF 167/816 reads (20%) | catalogued as COSV53498297; called by muse, mutect2, varscan2
- PCDHB6 | c.975A>C p.L325= | Silent (SNP) | VAF 181/467 reads (39%) | called by muse, mutect2
- POLA1 | c.855A>G p.Q285= | Silent (SNP) | VAF 28/606 reads (5%) | called by muse, mutect2
- PPP1R13L | c.177G>A p.P59= | Silent (SNP) | VAF 115/1138 reads (10%) | catalogued as rs372792420, COSV62908490; called by muse, mutect2
- SIPA1L1 | c.1911C>T p.A637= | Silent (SNP) | VAF 104/886 reads (12%) | called by muse, mutect2, varscan2
- ETNPPL | c.*57G>A | 3'UTR (SNP) | VAF 14/110 reads (13%) | called by muse, mutect2, varscan2
- HAPLN2 | c.440-62C>T | Intron (SNP) | VAF 19/163 reads (12%) | catalogued as rs1269150210; called by muse, mutect2, varscan2
- KPNA6 | c.-14C>G | 5'UTR (SNP) | VAF 44/353 reads (12%) | catalogued as rs369816810; called by muse, mutect2, varscan2
- MOGAT2 | c.650+18A>G | Intron (SNP) | VAF 98/393 reads (25%) | called by muse, mutect2, varscan2
- PRKCZ | c.552+39G>A | Intron (SNP) | VAF 58/233 reads (25%) | catalogued as rs776406535; called by muse, mutect2, varscan2
- TRPM8 | c.1362+98C>A | Intron (SNP) | VAF 3/49 reads (6%) | called by muse, mutect2
